FM case AD13780 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/14b0ede8-75f6-47ff-b489-cd5435276f66

Female, 84.1 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the overlapping lesion of nasopharynx; metastasis biopsied or resected from the nasal cavity. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
